Gene-level copy-number profile of tumor specimen TCGA-56-1622-01A from TCGA case TCGA-56-1622, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 58.5 years (21,371 days).
Specimen TCGA-56-1622-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.6e71cc60-4a8a-4738-8cc4-387e08cbccf7.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-56-1622-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/ac053026-6550-4fd2-9a77-47cd139a5a79

Most common (modal) total copy number across autosomal genes: 1 — below the diploid value of 2.
Genes by total copy number (all chromosomes): copy number 0: 28; copy number 1: 33,333; copy number 2: 20,883; copy number 3: 4,711; copy number 4: 348; copy number 5: 146; copy number 6: 318; copy number 7: 22; copy number 9: 2; copy number 12: 27.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-56-1622-01A-01D-0685-01): tumor purity 0.9, ploidy 1.73, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 28 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:117,544,205–117,544,311, 1 gene: RNU6-1200P.
- chr3:117,674,342–117,794,384, 3 genes: AC092691.2, LINC02024, AC092691.3.
- chr7:110,590,082–111,562,517, 6 genes (within-gene range 0–1): AC073326.2, IMMP2L, AC073326.1, LRRN3, AC003989.2, AC003989.1.
- chr7:145,583,197–145,681,369, 2 genes: DPY19L4P2, AC006007.1.
- chr8:3,700,492–3,700,628, 1 gene: RNA5SP251.
- chr10:87,751,512–87,845,612, 3 genes (within-gene range 0–1): ATAD1, CFL1P1, RN7SL78P.
- chr10:88,259,129–88,584,530, 2 genes (within-gene range 0–1): AL353149.1, RNLS.
- chr10:97,865,000–98,453,805, 10 genes (within-gene range 0–1): CRTAC1, AL355301.1, R3HCC1L, LOXL4, AL139241.1, PYROXD2, MIR1287, HPS1, MIR4685, AL139243.1.

Amplified relative to the modal value (total copy number ≥ 3, i.e. more than twice the modal value of 1; autosomes only): 5,574 genes in 31 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:126,180,012–126,517,773, 11 genes, copy number 5: ALDH1L1-AS2, AC079848.2, AC016924.1, AC063919.1, AC063919.2, KLF15, CCDC37-DT, CFAP100, AC073439.1, ZXDC, UROC1.
- chr3:127,165,506–127,390,670, 8 genes, copy number 5: AC112482.2, C3orf56, Y_RNA, AC112482.1, RNU6-1047P, AC133681.1, PRR20G, LINC02016.
- chr3:160,495,007–161,821,908, 20 genes, copy number 3: KPNA4, SCARNA7, KRT8P12, RPL6P8, ARL14, SNORA72, AC069224.1, PPM1L, B3GALNT1, NMD3, AC108738.1, EEF1GP4, PSMC1P7, SPTSSB, LINC02067, AC112491.1, RPL23AP42, OTOL1, AC112770.1, AC131211.1.
- chr3:162,601,627–185,501,109, 354 genes, copy number 3–12 (broad region; genes not listed).
- chr5:58,198–19,234,487, 353 genes, copy number 3 (broad region; genes not listed).
- chr7:102,699,228–106,036,432, 55 genes, copy number 3 (within-gene range 1–5): AC105052.5, FAM185A, AC105052.2, FBXL13, RNU6-1136P, RN7SKP198, LRRC17, NFE4, AC073127.1, ARMC10, CRYZP1, NAPEPLD, AC007683.1, RPL23AP95, AC007683.3, DPY19L2P2, S100A11P1, PMPCB, DNAJC2, PSMC2, RPS29P16, SLC26A5, Y_RNA, Y_RNA, AC005064.1, RELN, RN7SKP86, ORC5, LHFPL3, EIF4BP6, LHFPL3-AS1, AC091286.1, LHFPL3-AS2, RN7SL8P, AC007384.1, LINC01004, KMT2E-AS1, KMT2E, AC005070.3, SRPK2, AC005070.1, AC005070.2, AC004884.1, RWDD4P1, AC004884.2, RNU6-1322P, PUS7, AC073073.1, RINT1, EFCAB10, AC073073.2, YBX1P2, ATXN7L1, AC005099.1, CDHR3.
- chr8:37,736,601–40,016,391, 67 genes, copy number 3 (within-gene range 1–3) (broad region; genes not listed).
- chr8:42,484,600–52,460,959, 135 genes, copy number 3–4 (broad region; genes not listed).
- chr8:55,161,446–55,164,727, 1 gene, copy number 4: AC022679.1.
- chr8:57,994,509–58,204,279, 1 gene, copy number 3 (within-gene range 2–3): FAM110B.
- chr8:58,091,442–58,243,984, 3 genes, copy number 3 (within-gene range 2–3): AC027698.1, RPL26P26, AC092819.3.
- chr8:69,667,046–69,834,978, 1 gene, copy number 3 (within-gene range 2–3): SLCO5A1.
- chr8:69,713,390–145,066,685, 1,185 genes, copy number 3–4 (within-gene range 2–4) (broad region; genes not listed).
- chr10:2,368,561–5,945,900, 80 genes, copy number 3 (within-gene range 1–3) (broad region; genes not listed).
- chr11:13,756,027–13,758,345, 2 genes, copy number 7: CENPUP1, AC013828.1.
- chr11:14,262,846–22,813,055, 155 genes, copy number 4–12 (within-gene range 2–12) (broad region; genes not listed).
- chr11:24,235,477–25,631,041, 7 genes, copy number 4–9: LINC02686, Y_RNA, LUZP2, AC115990.1, AC087373.1, RPL36AP40, AC100770.1.
- chr11:26,667,020–26,723,427, 1 gene, copy number 5: SLC5A12.
- chr11:130,448,974–131,350,917, 15 genes, copy number 3: ADAMTS15, AP004371.1, BAK1P2, MIR8052, LINC02873, AP003486.2, PPP1R10P1, LINC02551, SNX19, AP003486.1, RN7SL167P, AP002856.3, AP002856.1, AP002856.4, AP002856.2.
- chr11:131,385,249–131,771,638, 5 genes, copy number 3: RNU6ATAC12P, AP003025.1, AP003025.2, NTM-AS1, AP004372.1.
- chr12:66,767–22,690,665, 626 genes, copy number 3 (broad region; genes not listed).
- chr12:22,722,229–22,743,091, 2 genes, copy number 3: RPS27P22, AC084819.1.
- chr12:24,967,127–31,615,666, 142 genes, copy number 3 (broad region; genes not listed).
- chr12:44,244,394–44,921,848, 5 genes, copy number 3 (within-gene range 1–3): AC025030.2, AC025030.1, AC025253.1, AC025253.2, NELL2.
- chr12:64,696,191–70,637,440, 130 genes, copy number 3 (broad region; genes not listed).
- chr12:71,439,798–78,213,010, 94 genes, copy number 3 (within-gene range 1–3) (broad region; genes not listed).
- chr12:81,868,368–87,170,429, 36 genes, copy number 3: AC091515.1, LINC02426, AC011602.1, CCDC59, METTL25, AC089998.3, AC089998.4, AC089998.2, AC089998.1, AC091214.1, TMTC2, RNU6-977P, RPL6P25, AC090680.1, AC093025.1, AC090679.3, AC090679.2, AC090679.1, AC087888.1, AC093027.1, SLC6A15, AC128657.1, TSPAN19, LRRIQ1, ALX1, LINC02820, AC126471.1, AC137768.1, RASSF9, NTS, MGAT4C, AC016993.1, AC139697.1, AC010196.1, AC079597.1, RPL23AP68.
- chr14:100,323,339–104,978,374, 261 genes, copy number 3 (broad region; genes not listed).
- chr20:51,831,797–55,781,231, 47 genes, copy number 3: LINC01429, RNU6-347P, RNU7-6P, ZFP64, AL109984.1, ERP29P1, LINC01524, AL109610.1, AL049765.2, AL049765.1, MRPS33P4, AL031674.1, AL161945.1, AL121902.1, RPL36P1, TSHZ2, RN7SKP184, AL391097.3, AL391097.1, AL391097.2, AL109930.1, AL354993.1, PPIAP10, AL354993.2, Y_RNA, AL157838.1, ZNF217, AC005808.1, RNU7-14P, AC005914.1, AC006076.1, SUMO1P1, BCAS1, AC005220.1, MIR4756, CYP24A1, AL133335.2, PFDN4, AL133335.1, DOK5, RNU4ATAC7P, RPL12P4, LINC01440, LINC01441, AL160413.1, AL109829.1, AL109828.1.
- chr21:10,328,411–34,360,033, 396 genes, copy number 3–5 (within-gene range 1–5) (broad region; genes not listed).
- chr22:15,290,718–50,801,309, 1,376 genes, copy number 3 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 30,952. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
